Somatic mutation profile of tumor specimen TCGA-FU-A3NI-01A (aliquot TCGA-FU-A3NI-01A-11D-A21Q-09) from TCGA case TCGA-FU-A3NI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 45.3 years (16,533 days).
Specimen TCGA-FU-A3NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 995dc84c-70da-47ef-94c6-097295d03e59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3NI-10A (Blood Derived Normal), aliquot TCGA-FU-A3NI-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d062548e-8b43-4fdf-8247-6f2a47c32660

The open-access MAF lists 104 somatic variants for this specimen: 75 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 25, Nonsense Mutation 5, Intron 3, Splice Region 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HCN1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs587777492, CM145436, COSV57516038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.748+1G>A p.X250_splice | Splice Site (SNP) | VAF 22/42 reads (52%) | catalogued as rs1131691535, COSV65041298; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV65535036; called by muse, mutect2, varscan2
- ADAMTS19 | c.2307A>T p.K769N | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV50754931; called by muse, mutect2, varscan2
- ADAMTS19 | c.3539G>A p.R1180Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as rs1389319442, COSV50754991; called by muse, mutect2, varscan2
- AFF3 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1383264450, COSV57856962, COSV57870376; called by muse, mutect2, varscan2
- ASMTL | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.179); catalogued as COSV67243935; called by muse, mutect2, varscan2
- BPTF | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs749305717, COSV58838837; called by mutect2, varscan2
- CEP41 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs138907207; called by muse, mutect2, varscan2
- CEP83 | c.1393A>G p.K465E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV60408824; called by muse, mutect2, varscan2
- CFH | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV62777778; called by muse, mutect2, varscan2
- CHRNB1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV60139465; called by muse, mutect2
- COL6A3 | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs755178814, COSV55080308; ClinVar: benign; called by muse, mutect2, varscan2
- CYLC2 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV66337904; called by muse, mutect2, varscan2
- DARS2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.053); catalogued as COSV53407389; called by muse, mutect2, varscan2
- DHX9 | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.084); catalogued as COSV62360078; called by muse, mutect2, varscan2
- DMD | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.257); catalogued as COSV55877803; called by muse, mutect2, varscan2
- DNAJC21 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs1450749654, COSV57760970; called by muse, mutect2, varscan2
- DPP8 | c.1651C>T p.H551Y (on ENST00000341861 / NM_001320875.2; = p.H535Y on NM_017743.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV55679576; called by muse, mutect2, varscan2
- DPPA3 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs772450929, COSV61502699, COSV61503143; called by muse, mutect2, varscan2
- DSCAML1 | c.1828C>T p.R610C (on ENST00000321322; = p.R550C on NM_020693.4) | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774937072, COSV58385083, COSV58392788; called by muse, mutect2, varscan2
- ENPP7 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs782158669, COSV60386876; called by muse, mutect2, varscan2
- EP300 | c.5155C>T p.Q1719* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV54334431; called by muse, mutect2, varscan2
- EZHIP | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.093); catalogued as rs782664899, COSV57956374; called by muse, mutect2, varscan2
- FBXO11 | c.1343G>A p.R448Q (on ENST00000403359 / NM_001190274.2; = p.R364Q on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV57020632; called by muse, mutect2, varscan2
- FLG | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.093); catalogued as rs111657882; called by muse, mutect2, varscan2
- GALC | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99729591; called by muse, mutect2
- GIP | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV62467311; called by muse, mutect2, varscan2
- GNPTAB | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV68449684; called by muse, mutect2, varscan2
- GRIA3 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52064265, COSV99988567; called by muse, mutect2, varscan2
- GULP1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV63067753, COSV63068504, COSV63076261; called by muse, mutect2, varscan2
- H1-5 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58898801; called by muse, mutect2, varscan2
- HOXC4 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57699256; called by muse, mutect2, varscan2
- HSPH1 | c.2354T>C p.I785T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100184884; called by muse, mutect2
- KCNH3 | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); catalogued as rs779021434, COSV57791244; called by muse, mutect2, varscan2
- KCNRG | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57248970, COSV57250037; called by muse, mutect2, varscan2
- KRT38 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV55846260; called by muse, mutect2, varscan2
- MAGED2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV54498156, COSV99514343; called by muse, mutect2, varscan2
- MAP4K2 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV53644471; called by muse, mutect2, varscan2
- MEGF8 | c.4289C>T p.A1430V (on ENST00000251268 / NM_001271938.2; = p.A1363V on NM_001410.3) | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs777183202, COSV52088566; called by muse, mutect2, varscan2
- MSRB3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs925203965, COSV57587286; called by muse, mutect2, varscan2
- MTTP | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV55506624; called by muse, mutect2, varscan2
- MYO10 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72563184; called by muse, mutect2, varscan2
- MYO1H | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752481845, COSV60446537; called by muse, mutect2, varscan2
- NLGN1 | c.1925A>G p.N642S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV64336290; called by muse, mutect2
- NLRC3 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs545030726, COSV57087372; called by muse, mutect2, varscan2
- NOD2 | c.1583dup p.D529Rfs*50 | Frame Shift Ins (INS) | VAF 10/20 reads (50%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, varscan2
- PACS2 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV57653678; called by muse, mutect2, varscan2
- PCDHA2 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as COSV65366388; called by muse, mutect2, varscan2
- PCNX4 | c.2345T>C p.V782A (on ENST00000406854 / NM_001330177.2; = p.V548A on NM_022495.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV58304980; called by muse, mutect2, varscan2
- PLOD1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV52145759; called by muse, mutect2
- PLXNA3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs368644346, COSV63754384; called by muse, mutect2, varscan2
- PLXNA4 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs777642451, COSV58110526; called by muse, mutect2, varscan2
- PTER | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV54346060; called by muse, varscan2
- REG1B | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV59306097; called by muse, mutect2, varscan2
- SALL1 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51758929; called by muse, mutect2, varscan2
- SAP130 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV52098377; called by muse, mutect2, varscan2
- SLC14A2 | c.1350C>T p.S450= | Splice Region (SNP) | VAF 6/33 reads (18%) | catalogued as rs140835811; called by muse, mutect2, varscan2
- SLC26A4 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as rs200706874, COSV55915497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC27A5 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV54020109; called by muse, mutect2, varscan2
- SRRM4 | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.372); catalogued as COSV57418254; called by muse, mutect2, varscan2
- STARD6 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756363417, COSV57142498; called by muse, mutect2, varscan2
- SVIL | c.159C>T p.I53= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs540544541, COSV63444209; called by muse, mutect2
- SYN1 | c.1132A>C p.K378Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55982288; called by muse, mutect2, varscan2
- TLR7 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV66124517; called by muse, mutect2, varscan2
- TMEM30B | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs756178430, COSV63133682; called by muse, mutect2, varscan2
- UNK | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV53142580, COSV53142955; called by muse, mutect2, varscan2
- USP11 | c.2138G>A p.R713H (on ENST00000218348; = p.R670H on NM_001371072.1) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as rs1468669616, COSV54474057; called by muse, mutect2, varscan2
- USP34 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1367204581, COSV68402155; called by muse, mutect2, varscan2
- UTRN | c.7923C>G p.N2641K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62309977; called by muse, mutect2
- WIPF1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.336); catalogued as rs770105478, COSV55816381, COSV55816628; called by muse, mutect2, varscan2
- ZNF808 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs776930729, COSV63120226; called by muse, mutect2, varscan2
- POTEM | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- SEMA3E | c.1887_1893del p.D629Efs*12 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- ARNT2 | c.378C>A p.G126= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57585654, COSV57586428; called by muse, mutect2, varscan2
- BLMH | c.696C>T p.T232= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV55585794; called by muse, mutect2, varscan2
- COL22A1 | c.4470G>A p.A1490= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs748451665, COSV57341187; called by muse, mutect2, varscan2
- GNPTAB | c.1491A>T p.G497= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV68449682; called by muse, mutect2, varscan2
- HTR4 | c.66G>A p.L22= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs201439456, COSV58796745; called by muse, mutect2, varscan2
- JADE1 | c.1083C>T p.F361= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV56906550, COSV99885584; called by muse, mutect2, varscan2
- JAG2 | c.1011C>T p.D337= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs369610323; called by muse, mutect2, varscan2
- KIAA1755 | c.1395G>A p.E465= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs554195759, COSV54077273; called by mutect2, varscan2
- KIRREL2 | c.42C>T p.F14= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs761338640, COSV52877198; called by muse, mutect2, varscan2
- LIG4 | c.1953C>T p.N651= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs780588115, COSV63597241; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC14B | c.99C>G p.L33= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV52048860; called by muse, mutect2, varscan2
- MAGI2 | c.2631C>G p.G877= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV62667988; called by muse, mutect2, varscan2
- MAGT1 | c.183C>T p.F61= (on ENST00000618282 / NM_001367916.1; = p.F93= on NM_032121.5) | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV63782005; called by muse, mutect2, varscan2
- MGAT4B | c.1557C>T p.F519= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs769211175, COSV52977282; called by muse, mutect2, varscan2
- OFD1 | c.108C>G p.L36= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV60796411, COSV60798975; called by muse, mutect2, varscan2
- PTBP1 | c.918C>T p.G306= (on ENST00000349038 / NM_031991.4; = p.G332= on NM_002819.5) | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs774884129, COSV100608615; called by muse, mutect2, varscan2
- PTPRR | c.1824G>A p.L608= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV51735185; called by muse, mutect2, varscan2
- SKOR1 | c.2829C>T p.F943= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV58244318, COSV58246818; called by muse, mutect2, varscan2
- SLC35A5 | c.537A>G p.G179= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV53727066; called by muse, mutect2, varscan2
- SWSAP1 | c.564G>A p.G188= (on ENST00000312423; = p.G209= on NM_175871.4) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55800589; called by muse, mutect2
- SYNDIG1 | c.12C>T p.I4= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV65235813; called by muse, mutect2, varscan2
- TANC1 | c.1083C>T p.P361= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV55089492; called by muse, mutect2, varscan2
- ZNF358 | c.150C>G p.L50= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV51176554; called by muse, mutect2, varscan2
- ZNF599 | c.1047G>A p.T349= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs769513345, COSV61396145; called by muse, mutect2, varscan2
- ZNF746 | c.1917C>T p.T639= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV61407737; called by muse, mutect2, varscan2
- EIF3A | c.1327-396C>G | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as COSV64961738; called by muse, mutect2, varscan2
- R3HDM1 | c.2047+4024del | Intron (DEL) | VAF 57/153 reads (37%) | called by mutect2, pindel, varscan2
- SNORD114-13 | n.66G>A | RNA (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- SVIL | c.827+5527C>A | Intron (SNP) | VAF 7/41 reads (17%) | catalogued as COSV63444206; called by muse, mutect2, varscan2
